Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3IS, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3IS-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age):

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Location:

Service: urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

Bladder cancer. Large T1, probable T2 cancer

Specimens Submitted:

- 1: SP: Bladder, prostate, seminal vesicles, peri-vesicle tissues; radical cystoprostatectomy
- 2: SP: Lymph nodes, right pelvic; dissection
- 3: SP: Urachus; biopsy
- 4: SP: Lymph nodes, retroperitoneal; dissection
- 5: SP: Lymph nodes, left pelvic; biopsy
- 6: SP: Vas deferens, left; biopsy
- 7: SP: Vas deferens, right; biopsy
- 8: SP: Ureter, left distal; biopsy
- 9: SP: Right periureteral tissue; biopsy
- 10: SP: Ureter, right; biopsy

DIAGNOSIS:

1. SP: Bladder, prostate, seminal vesicles, peri-vesicle tissues; radical cystoprostatectomy

a.

Tumor Type:

Invasive urothelial carcinoma, NOS

ICD-O-3
carcinoma, urothelial, NOS 8/20/3
Site: bladder, NOS C47.9
lw 12/7/11

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

Pattern of growth of the Invasive component:

Inverted / Nodular

Tumor Multicentricity:

Identified

Bladder Local Invasion:

Superficial half of muscularis propria

Extravesical Tumor Extension:

Ureters uninvolved

Urethra uninvolved

Free floating urothelial fragments with atypia in the section from urethral margin, however the attached lining at the margin and rest of the urethra benign

Vascular Invasion:

Not identified

Just/Syncytio: ovs Primary tested	X	

lw 12/7/11

[page 2 of 7]
SURGICAL PATHOLOGY REPORT

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting proliferative cystitis (Brunn's nests, cystitis cystica, cystitis glandularis)

Prostate:

Nodular hyperplasia

Other Prostatic adenocarcinoma (see prostate worksheet)

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT2a (Invades superficial half of muscularis propria)

PR0 (No involvement of prostate)

b.

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:3

Total Gleason score:6

A very minute component of pattern 4 is also present

Tumor Location:

Involves Right anterior

Involves Left anterior

Dominant tumor mass located in: no dominant mass, only small foci of carcinoma are present

Vascular Invasion:

Not Identified

Perineural Invasion:

Not identified

Tumor Multicentricity:

Multicentric foci of invasive carcinoma are present

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Tumor confined to prostate

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

Exhibits nodular hyperplasia

[page 3 of 7]
SURGICAL PATHOLOGY REPORT

Staging (AJCC 1997):

pT2b (confined to the prostate & capsule, involving both lobes)

2. SP: Lymph nodes, right pelvic; dissection

Lymph Nodes:

Not involved

Number of nodes examined: 2

3. SP: Urachus; biopsy

Benign fibroadipose tissue.

4. SP: Lymph nodes, retroperitoneal; dissection

Lymph Nodes:

Not identified

Benign fibroadipose tissue; entirely submitted

5. SP: Lymph nodes, left pelvic; biopsy

Lymph Nodes:

Not involved

Number of nodes examined: 4

6. SP: Vas deferens, left; biopsy

Benign segment of vas deferens.

7. SP: Vas deferens, right; biopsy

Benign segment of vas deferens.

8. SP: Ureter, distal left; biopsy

Benign segment of ureter.

9. SP: Right periureteral tissue; biopsy

Benign fibroadipose tissue.

10. SP: Ureter, right; biopsy

Benign segment of ureter

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1.) The specimen is received fresh labeled, "bladder, prostate, seminal vesicles, perivesical tissue". It consists of a bladder, prostate and seminal vesicles in one piece measuring 12.5 cm from superior to inferior, 11.0 cm laterally and 9.5 cm from anterior

[page 4 of 7]
SURGICAL PATHOLOGY REPORT

to posterior. The anterior aspect of the bladder is inked black and the posterior blue. The prostatic urethral margin is shaved and submitted. The prostate measures 5.0 x 4.5 x 3.7 cm, the right seminal vesicle measures 2.5 x 1.0 x 0.5 cm, the right vas deferens measures 9.5 cm in length and 0.5 cm in average diameter, the left seminal vesicle measures 2.8 x 1.1 x 0.5, and the left vas deferens 5 cm in length and 0.5 cm in average diameter. The bladder is opened along the anterior midline to reveal a large fungating tumor measuring 12.5 x 11.0 x 1.8 cm involving approximately 80% of the urothelial surface. The tumor is sectioned to reveal tan papillary friable cut surface involving the muscularis propria. Extension to the inked fat is grossly not identified. The remaining bladder mucosa is tan and focally hemorrhagic. Discrete perivesical lymph nodes are grossly not identified. The prostate is serially sectioned to reveal vaguely nodular parenchyma. Representative sections are submitted. T is submitted. The specimen is photographed.

Summary of sections:

UTHM -- urethral margin
RUM-- right ureter margin
LUM -- left ureter margin
T - tumor
RUO -- right ureter orifice
LUO-- left ureter orifice
LPW -- left posterior wall
LAW -- left anterior wall
RPW -- right posterior wall
RAW-- right anterior wall
TRI -- trigone
DOM-- dome
F -- perivesical fat
RSV -- right seminal vesicle
LSV -- left seminal vesicle
RA -- right apex prostate
LA -- left apex prostate
RAM -- right anterior mid prostate
RPM -- right posterior mid prostate
LAM -- left anterior mid prostate
LPM -- left posterior mid prostate
RAB -- right anterior base prostate
RPB -- right posterior base prostate
LAB -- left anterior base prostate
LPB -- left posterior base prostate

2).The specimen is received fresh, labeled "right pelvic lymph nodes" and consists of two pink tan firm lymph nodes ranging from 0.3 and 1.3 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes

3).The specimen is received fresh, labeled "part of urachus" and consists of yellow-tan fatty tissue measuring 1.5 x 1.0 x 1.0 cm. Representative sections are submitted.

Summary of sections:

U-undesignated

4).The specimen is received fresh, labeled "retroperitoneal lymph nodes" and consist yellow-tan fatty tissue measuring 0.5 x 0.5 x 0.3 cm. No lymph node is identified. All tissue submitted.

Summary of sections:

[page 5 of 7]
SURGICAL PATHOLOGY REPORT

U-undesignated

5). The specimen is received fresh, labeled "left pelvic lymph nodes" and consist of multiple pink tan firm lymph nodes ranging from 0.3 to 1.7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
BLN-- bisected lymph nodes

6). The specimen is received in formalin, labeled "Left vas deferens" and consists of an unoriented segment of pink-tan tubular tissue measuring 7.4 cm in length and 0.3 cm in maximum diameter, with scant pink white soft tissue attached. On cut section, a pinpoint lumen is identified. No abnormalities are grossly noted. Representative sections of the specimen are submitted.

Summary of sections:
E - ends
C - center

7). The specimen is received in formalin, labeled "Right vas deferens" and consists of an unoriented segment of pink-tan tubular tissue measuring 4.2 cm in length and 0.2 cm in maximum diameter, with scant pink white soft tissue attached. On cut section, a pinpoint lumen is identified. No abnormalities are grossly noted. Representative sections of the specimen are submitted.

Summary of sections:
E - ends
C - center

8). The specimen is received in formalin, labeled "Distal left ureter" and consists of an unoriented segment of ureter measuring 2 cm in length and 0.3 cm in maximum diameter. One end is slightly larger and appears hemorrhagic, inked black. The specimen is serially sectioned from the inked to the opposite end to reveal a patent stellate lumen, with a pink-tan grossly unremarkable mucosa. The adipose tissue is trimmed off, and the ureter is entirely submitted.

Summary of sections:
I - inked end
SS - remaining serial sections from inked to opposite end
OE - opposite end

9). The specimen is received in formalin, labeled "Right periureteral tissue" and consists of a fragment of grossly unremarkable fatty tissue 1.3 x 1.0 x 0.1 cm, which is entirely submitted.

Summary of sections:
U-undesignated

10). The specimen is received in formalin, labeled "Right ureter" and consists of an unoriented segment of ureter measuring 2.4 cm in length, and 0.4 cm in maximum diameter, with attached grossly unremarkable adipose tissue. One end of the specimen is slightly larger, appears to been previously incised and is focally hemorrhagic. This end has been inked black. The specimen is serially sectioned from the inked to the opposite end to reveal patent stellate lumen and grossly unremarkable pink-tan mucosa. The specimen is entirely submitted.

Summary of sections:
I - inked end
SS - remaining serial sections from inked to opposite end
OE - opposite end

[page 6 of 7]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

Part 1: SP: Bladder, prostate, seminal vesicles, peri-vesicle tissues; radical cystoprostatectomy

Block	Sect. Site	PCs
1	dom	1
1	f	1
1	la	1
1	lab	1
1	lam	1
1	law	1
1	lpb	1
1	lpm	1
1	lpw	1
1	lsv	1
1	lum	1
1	luo	1
1	ra	1
1	rab	1
1	ram	1
1	raw	1
1	rpb	1
1	rpm	1
1	rpw	1
1	rsv	1
1	rum	1
1	ruo	1
2	t	2
1	tri	1
1	uthm	1

Part 2: SP:Lymph nodes, right pelvic; dissection

Block	Sect. Site	PCs
1	BLN	0
1	LN	0

Part 3: SP:Urachus; biopsy (axm)

Block	Sect. Site	PCs
1	U	0

Part 4: SP: Lymph nodes, retroperitoneal; dissection

Block	Sect. Site	PCs
1	U	0

Part 5: SP: Lymph nodes, left pelvic; biopsy

Block	Sect. Site	PCs
3	BLN	0

Part 6: SP: Vas deferens, left; biopsy

Block	Sect. Site	PCs
1	c	1
1	e	1

Part 7: SP: Vas deferens, right; biopsy

Block	Sect. Site	PCs
1	c	1

[page 7 of 7]
SURGICAL PATHOLOGY REPORT

1 e 1

Part 8: SP: Ureter, left distal, biopsy

Block	Sect. Site	PCs
1	i	1
1	oe	1
2	ss	2

Part 9: SP: Right periureteral tissue; biopsy

Block	Sect. Site	PCs
1	u	1

Part 10: SP: Ureter, right; biopsy

Block	Sect. Site	PCs
1	i	1
1	oe	1
2	ss	2

Source: NCI Genomic Data Commons file 22f0c7dc-f093-4751-9b02-36540ab8ac94 (TCGA-DK-A3IS.2387C5D6-37CA-40C0-A122-228070BEE480.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).